TCGA case TCGA-XF-AAN1 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5378f375-aa04-4eca-bc35-190b3efb52bc

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Dead; Days to death: 941 days (2.6 years).

Diagnoses (4)
1. Papillary transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8130/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 75.8 years (27,687 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 0; Lymph nodes tested: 53; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Days to treatment start: 0 days; Days to treatment end: 0 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Days to treatment start: 0 days; Days to treatment end: 0 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 71.5 years (26,099 days); Days to diagnosis: -1,588 days (-4.3 years); AJCC pathologic T: T1.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Days to treatment start: -918 days (-2.5 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days; Treatment anatomic sites: Bladder.
   Recorded as not given: Radiation Therapy, NOS.
3. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Treatment intent type: Induction; Timepoint category: Prior to Procurement.
4. Recurrence of diagnosis 1 (Papillary transitional cell carcinoma), site: Pelvis, NOS. Age at diagnosis: 77.6 years (28,337 days); Days to diagnosis: 650 days (1.8 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 650 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 650 days (1.8 years).
- Days to follow up: 941 days (2.6 years); Disease response: With Tumor.
- Karnofsky performance status: 80.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 92 kg; Height: 168 cm; BMI: 32.6.

Exposures
- Occupation type: Finance Professionals.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 47; Tobacco smoking quit year: 1994; Age at onset: 19.

Family history
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Gastric Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-AAN1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 710 mg.
  Slide TCGA-XF-AAN1-01A-03-TSC: Section location: Top; Percent tumor cells: 78; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 18; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XF-AAN1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-AAN1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: retired; Occupation primary: accountant; Occupation primary industry: office/business; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: No; Treatment outcome first course: Partial Remission/Response.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Bacillus Calmette-Guerin (BCG); Bcg treatment 90 days prior to resection: No; Bcg treatment complete response: No; Bcg treatment induction courses indicator: Yes; Bcg treatment maintenance courses indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: BCG.
- Drug treatment 2: Pharmaceutical therapy drug name: BCG; Treatment best response: Clinical Progressive Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: Urothelial Carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Turbt.
- Other malignancy form, Drug treatment, Administered drug: Pharmaceutical therapy drug name: BCG.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 941 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 941 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 650 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-AAN1-01A-31D-A42D-01): tumor purity 0.91, ploidy 1.95, whole-genome doublings 0.
